Somatic mutation profile of tumor specimen C3N-03088-01 (aliquot CPT0209440005) from CPTAC case C3N-03088, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 31.7 years (11,589 days).
Specimen C3N-03088-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Occipital Cortex; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f657d634-0df8-4aa8-921d-8115c93e603e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03088-31 (Blood Derived Normal), aliquot CPT0209480002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/badc6c41-47fc-4340-a73e-b781c1abc1a7

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/219 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CYP19A1 | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs761722363, COSV53057118; called by muse, mutect2, varscan2
- EYS | c.3635G>T p.C1212F | Missense Mutation (SNP) | VAF 18/183 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.151); catalogued as rs780456521; called by muse, mutect2
- ANKRD39 | c.497T>G p.L166R | Missense Mutation (SNP) | VAF 81/324 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- F8 | c.466G>T p.V156F | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- LTBP4 | c.1097G>A p.R366H (on ENST00000308370 / NM_001042544.1; = p.R329H on NM_003573.2) | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- MAGEC3 | c.802C>A p.Q268K | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.763); called by muse, mutect2
- OAS2 | c.491A>G p.K164R | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- RIMS1 | c.1793G>A p.G598E | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TJP2 | c.521G>T p.S174I | Missense Mutation (SNP) | VAF 45/517 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.372); called by muse, mutect2
- CYP2U1 | c.1329A>G p.L443= | Silent (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2, varscan2
- GNAL | c.897C>T p.F299= (on ENST00000269162 / NM_001142339.3; = p.F376= on NM_182978.4) | Silent (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- MAGEB3 | c.837C>T p.A279= | Silent (SNP) | VAF 8/152 reads (5%) | called by muse, mutect2
- TTYH2 | c.1512C>T p.S504= | Silent (SNP) | VAF 44/292 reads (15%) | catalogued as rs144976577; called by muse, mutect2, varscan2
- EFNB1 | c.*11C>T | 3'UTR (SNP) | VAF 26/275 reads (9%) | catalogued as rs781189322; called by muse, mutect2, varscan2
- EPOR | c.251+94G>A | Intron (SNP) | VAF 76/540 reads (14%) | called by muse, mutect2, varscan2
